Somatic mutation profile of tumor specimen TARGET-10-PASLZM-03A (aliquot TARGET-10-PASLZM-03A-01D) from TARGET case TARGET-10-PASLZM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.8 years (2,496 days).
Specimen TARGET-10-PASLZM-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43f9b8d5-3d22-4a3a-8622-481357d3dd38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASLZM-10A (Blood Derived Normal), aliquot TARGET-10-PASLZM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7497329c-bd3f-4aaf-90a0-5fa1fff611ac

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLASP2 | c.2903C>T p.A968V (on ENST00000359576; = p.A967V on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/606 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs373215296; called by muse, mutect2, varscan2
- CNNM4 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs147976284; called by mutect2, varscan2
- DST | c.6034G>A p.D2012N | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs746717062, COSV55019181; called by muse, mutect2, varscan2
- MARF1 | c.4148C>T p.S1383L | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs779042389, COSV60027314; called by mutect2, varscan2
- NBPF15 | c.1792G>T p.V598L | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.312); called by muse, varscan2
- KLHL32 | c.552G>A p.T184= | Silent (SNP) | VAF 26/190 reads (14%) | catalogued as rs202093124, COSV65113937; called by muse, mutect2, varscan2
- OR5K4 | c.756C>T p.Y252= | Silent (SNP) | VAF 24/260 reads (9%) | catalogued as rs752278724, COSV61584136; called by muse, mutect2
- PSME4 | c.3324A>G p.Q1108= | Silent (SNP) | VAF 119/1108 reads (11%) | catalogued as rs1345595403, COSV66366820; called by muse, varscan2
- VWF | c.399C>T p.A133= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as COSV54629915; called by muse, mutect2
